Surgical pathology report (de-identified scan), TCGA case TCGA-E5-A2PC, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Roswell Park, specimen TCGA-E5-A2PC-01A (Primary Tumor).

[page 1 of 4]
**SPECIMENS:**

- A. LEFT URETER
- B. RIGHT URETER
- C. BLADDER, TUBES, OVARIES, VAGINAL WALL
- D. LEFT URETERAL FINAL MARGIN
- E. RIGHT URETERAL FINAL MARGIN
- F. LEFT COMMON ILIAC LYMPH NODES
- G. LEFT OBTURATOR LYMPH NODES
- H. LEFT ILIAC ARTERY LYMPH NODES
- I. LEFT ILIAC VEIN LYMPH NODES
- J. RIGHT ILIAC VEIN LYMPH NODES
- K. RIGHT ILIAC ARTERY LYMPH NODES
- L. RIGHT OBTURATOR LYMPH NODES
- M. RIGHT COMMON ILIAC LYMPH NODES

ICD - 0 - 3

carcinoma, wrothelial, NOS 8/20/3

Site: bladder, wall, lateral C67.2

fw 8/24/11

SPECIMEN(S):

- A. LEFT URETER
- B. RIGHT URETER
- C. BLADDER, TUBES, OVARIES, VAGINAL WALL
- D. LEFT URETERAL FINAL MARGIN
- E. RIGHT URETERAL FINAL MARGIN
- F. LEFT COMMON ILIAC LYMPH NODES
- G. LEFT OBTURATOR LYMPH NODES
- H. LEFT ILIAC ARTERY LYMPH NODES
- I. LEFT ILIAC VEIN LYMPH NODES
- J. RIGHT ILIAC VEIN LYMPH NODES
- K. RIGHT ILIAC ARTERY LYMPH NODES
- L. RIGHT OBTURATOR LYMPH NODES
- M. RIGHT COMMON ILIAC LYMPH NODES

GROSS DESCRIPTION:**A. LEFT URETER**

Received fresh for frozen section is a tan pink tubular segment of ureter 0.3cm in length and 0.4cm in diameter. Toto FSA

B. RIGHT URETER

Received fresh for frozen section is a tan pink tubular segment of ureter 0.5cm in length and 0.4cm in diameter. Toto FSB

C. BLADDER, TUBES, OVARIES AND VAGINAL WALL

Received fresh in a matching container and subsequently fixed in formalin is a cystectomy and bilateral salpingo-oophorectomy specimen measuring overall 14.5 x 10.5 x 6.1 cm, including the urinary bladder (7 x 6 x 1.5 cm) and peri-cystic fatty tissue. The posterior fatty margin is inked black and the anterior surface blue. A portion of tan smooth vaginal wall is demonstrated measuring 4 x 3cm. The urinary bladder is opened from the anterior aspect to reveal a fungating mass present on the right posterior lateral wall of the bladder with surface hemorrhage and ulceration, measuring 4.6 x 3.0 x 1.1 cm. The tumor is 2.5 cm from the closest urethral margin. The tumor appears to invade into the muscularis propria but not in the perivesicular fat. The tumor involves right ureter orifice but grossly does not appear to involve the right ureter. The remainder of the bladder mucosa is pink-tan and focally edematous. No other lesions are identified. The attached right fallopian tube is 5 cm long x 0.3 cm in diameter, with a paratubal cyst 1.5 x 0.9 x 0.9 cm. The right ovary is 2 x 1.5 x 0.5 cm, The left fallopian tube is 4.2 cm long x 0.4 cm in diameter with fimbriated end. The left ovary is 2 x 1 x 1 cm. The posterior aspect of the uterus is covered with pink-tan smooth vaginal mucosa (6.4 x 3.2 cm). Careful palpation and dissection of perivesicle tissue reveals three possible lymph nodes. Representative sections are submitted as follows:

- C1: urethral margin and right ureteral margin
- C2: left ureter margin and tumor with respect to posterior neck region
- C3: tumor with posterior bladder wall
- C4: representative section of tumor
- C5: tumor and posterior bladder wall
- C6: tumor with adjacent right ureter
- C7: tumor and adjacent dome
- C8: sections from anterior bladder wall
- C9: trigone area into the left ureter

[page 2 of 4]
TSS:

- C10: left lateral bladder wall
- C11: bladder neck
- C12: right tube and ovary
- C13: left tube and ovary
- C14: three presumed lymph nodes for microscopic examination
- C15-C16: Vaginal tissue

D. LEFT URETER FINAL MARGIN

Received in formalin within a white clip is a tubular piece of tan tissue measuring 0.4 cm in length and 0.7 cm in diameter. The lumen is 0.4 cm. After removal of the clip, tissue is submitted entirely in cassette D1.

E. RIGHT URETER FINAL MARGIN

Received in formalin within a white surgical clip is a tubular piece of tan tissue measuring 0.6 cm in length and 0.7 cm in diameter. The lumen is 0.3 cm. After removal of clip, the tissue is submitted entirely in cassette E1.

F. LEFT COMMON ILIAC LYMPH NODE

Received in formalin is a piece of yellow-tan soft tissue measuring 2.4 x 2.4 x 0.9 cm. One lymph node is identified measuring 2.4 cm. It is bisected and has a variegated yellow-brown cut surface. Specimen is submitted entirely as follows:

F1: lymph node

F2: remainder of soft tissue

G. LEFT OBTURATOR LYMPH NODE

Received in formalin are pieces of yellow-tan soft tissue in aggregate measuring 3.5 x 2.5 x 0.8 cm. Four lymph nodes identified ranging in size from 0.7 to 2 cm. Specimen is submitted entirely as follows:

G1: 3 lymph nodes

G2: 1 lymph node

G3: remainder of soft tissue

H. LEFT ILIAC ARTERY LYMPH NODE

Received in formalin of an aggregate yellow-tan soft tissue measuring 2.5 x 2.3 x 0.9 cm. Three lymph nodes identified ranging in size from 0.4 to 1.6 cm. Specimen is submitted entirely as follows:

H1: lymph nodes

H2: remainder of soft tissue

I. LEFT ILIAC VEIN LYMPH NODE

Received in formalin is a piece of yellow-tan soft tissue measuring 1.5 x 1 x 0.2 cm. No distinct lymph node is identified. Specimen is submitted entirely in cassette I1.

J. RIGHT ILIAC VEIN LYMPH NODE

Received in formalin are pieces of yellow-tan soft tissue in aggregate measuring 3.3 x 2.5 x 0.8 cm. No distinct lymph node is identified. Specimen is submitted entirely in cassettes J1-J2.

K. RIGHT ILIAC ARTERY LYMPH NODE

Received in formalin are pieces of yellow-tan soft tissue in aggregate measuring 3.2 x 2.6 x 0.6 cm. Three lymph nodes identified ranging in size from 1.2 to 2.5 cm. Specimen is submitted entirely as follows:

K1: 2 lymph nodes

K2: 1 lymph node

K3: remainder of soft tissue

L. RIGHT OBTURATOR LYMPH NODE

Received in formalin is a piece of yellow-tan soft tissue measuring 4.4 x 3.2 x 1.3 cm. Two lymph nodes identified measuring 2.5 and 2.7 cm. The one lymph node is bisected and has a hemorrhagic core. The specimen is submitted entirely as follows:

L1-L2: 1 lymph node each

L3: remainder of soft tissue

M. RIGHT COMMON ILIAC LYMPH NODE

Received in formalin is an aggregate of yellow-tan soft tissue measuring 4.4 x 4.2 x 1.2 cm. Four lymph nodes are identified ranging in size from 1.2 to 1.8 cm. Specimen is submitted entirely as follows:

M1: 3 lymph nodes

M2: 1 lymph node

M3: remainder of soft tissue

DIAGNOSIS:

A. LEFT URETER MARGIN, EXCISION:

- BENIGN UROTHELIUM AND STROMA, NEGATIVE FOR TUMOR

B. RIGHT URETER MARGIN, EXCISION:

[page 3 of 4]
TSS:

- BENIGN UROTHELIUM AND STROMA, NEGATIVE FOR TUMOR
- C. BLADDER, TUBES, OVARIES AND VAGINAL WALL, CYSTECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- HIGH-GRADE UROTHELIAL CARCINOMA, TUMOR SIZE 4.6 X 3.0 X 1.1 CM, INVADING INTO MUSCULARIS PROPRIA OF RIGHT POSTERIOR LATERAL WALL OF URINARY BLADDER
- BILATERAL URETERAL MARGIN AND URETHRAL MARGIN, NEGATIVE FOR TUMOR
- FOLLICULAR CYSTITIS AND PAPILLARY UROTHELIAL HYPERPLASIA IN SURROUNDING BLADDER TISSUE
- ONE LYMPH NODE IN PERIVESICAL ADIPOSE TISSUE, NEGATIVE FOR TUMOR (0/1)
- ATTACHED PORTION OF VAGINA AND MARGIN, NEGATIVE FOR TUMOR
- BILATERAL OVARY SHOWING EPITHELIAL INCLUSION CYSTS, NEGATIVE FOR TUMOR
- BILATERAL FALLOPIAN TUBE WITH PARATUBAL CYSTS
- D. LEFT URETER FINAL MARGIN, EXCISION:
- BENIGN UROTHELIUM AND STROMA, NEGATIVE FOR TUMOR
- E. RIGHT URETER FINAL MARGIN, EXCISION:
- BENIGN UROTHELIUM AND STROMA, NEGATIVE FOR TUMOR
- F. LEFT COMMON ILIAC LYMPH NODES, EXCISION:
- TWO LYMPH NODES, NEGATIVE FOR TUMOR (0/2)
- G. LEFT OBTURATOR LYMPH NODES, EXCISION:
- FIVE LYMPH NODES, NEGATIVE FOR TUMOR (0/5)
- H. LEFT ILIAC ARTERY LYMPH NODES, EXCISION:
- SIX LYMPH NODES, NEGATIVE FOR TUMOR (0/6)
- I. LEFT ILIAC VEIN LYMPH NODES, EXCISION:
- BENIGN ADIPOSE TISSUE, NO LYMPH NODES ARE IDENTIFIED
- J. RIGHT ILIAC VEIN LYMPH NODE, EXCISION:
- BENIGN ADIPOSE TISSUE, NO LYMPH NODES ARE IDENTIFIED
- K. RIGHT ILIAC ARTERY LYMPH NODES, EXCISION:
- THREE LYMPH NODES, NEGATIVE FOR TUMOR (0/3)
- L. RIGHT OBTURATOR LYMPH NODES, EXCISION:
- METASTATIC UROTHELIAL CARCINOMA PRESENT IN ONE OUT OF SIX LYMPH NODES (1/6)
- M. RIGHT COMMON ILIAC LYMPH NODES, EXCISION:
- FIVE LYMPH NODES, NEGATIVE FOR TUMOR (0/5)

SYNOPTIC REPORT - URINARY BLADDER, URETER AND RENAL PELVIS

Specimen Type: Total cystectomy with bilateral salpingo-oophorectomy and portion of vaginal wall
Tumor Site: Right lateral wall
Posterior wall
Tumor Size: Greatest dimension: 4.6cm
Additional dimensions: 3cm x 1.1cm
WHO Classification
Infiltrating urothelial carcinoma 8120/3
High Grade
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L): Indeterminate
Perineural Invasion: Absent
Direct Extension of Invasive Tumor: None identified
Lymph nodes: Positive 1 / 28
Margins of Resection: Free

[page 4 of 4]
TSS:

Additional Pathologic Findings: Inflammation/regenerative changes
p53 stain result: Positive 70% Low Intensity
Pathological Staging (pTNM): T 2b N 1 M X

CLINICAL HISTORY:

None provided

PRE-OPERATIVE DIAGNOSIS:

Bladder Cancer

INTRAOPERATIVE CONSULTATION:

FSA-FSB: No tumor seen. Diagnosis called to Dr. at [redacted] by Dr.

Gross Dictation: .., Pathologist,
Microscopic/Diagnostic Dictation: Pathologist,
Final Review:.., Pathologist,
Microscopic/Diagnostic Dictation: Pathologist
Final Review:.., Pathologist,
Final Review:.., Pathologist.
Final:.., Pathologist,

Source: NCI Genomic Data Commons file ed879bd4-e0e3-44d1-af44-8e6527b8be1f (TCGA-E5-A2PC.7E6EAFBD-51DD-4E4A-86F7-20CAA317F849.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).